Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5985, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5985-01A (Primary Tumor).

[page 1 of 6]
PATHOLOGIC DIAGNOSIS:

A. SPECIMEN DESIGNATED "RIGHT KIDNEY":

RENAL CELL CARCINOMA, clear cell type (7.2 cm).

Fuhrman nuclear grade II (of IV).

Tumor is limited to the kidney.

Deep (Gerota's fascia) margin is negative for tumor.

Renal vein, artery, and ureter margins are negative for tumor.

No lymphovascular invasion is identified.

B. SPECIMEN DESIGNATED "REGIONAL NODES":

Lymph node fragments, negative for tumor.

CLINICAL DATA:

Operation: Nephrectomy.

Clinical Diagnosis: As above.

TISSUE SUBMITTED:

A/1) right kidney.

B/2) regional nodes.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patients name and unit number.

Part A, labeled "#1 - right kidney", consists of a 1056 gram right radical nephrectomy specimen, including kidney (15.0 x 8.8 x 5.8 cm) and abundant surrounding tan/white perirenal disrupted adipose tissue up to 8.0 cm in thickness. Extending from the renal pelvis is a ureter (2.5 cm in length x 0.4 cm in diameter), renal vein (0.8 cm in length x 0.4 cm in diameter), two renal arteries (0.9 x 0.4 cm and 1.6 x 0.3 cm), and a second renal vein (0.6 cm in length x 0.6 cm in diameter). An adrenal gland is not grossly identified. Gerota's fascia is inked black, and the specimen is bivalved to reveal a 7.2 x 5.0 x 6.0 cm tan/yellow to tan/red multinodular, focally cystic and necrotic mass in the renal cortex. The mass is 0.3 cm from the deep soft tissue mass, 2.5 cm from renal artery #2, 2.2 cm from renal vein #2, 5.0 cm from renal artery #1, and 5.2 cm from the ureter. Gross photographs are taken. The tumor appears to distort but not invade the renal capsule. The tumor grossly abuts but does not invade into the perinephric adipose tissue. The tumor extends into the renal pyramids, but does not grossly invade into the renal sinus fat. There is no gross invasion of the renal vein. The remainder of the renal cortex is tan/brown with a well-defined corticomedullary junction. The pelvis and calyces are covered by smooth, glistening mucosa. The perirenal adipose tissue is thinly sectioned and no lymph nodes are grossly identified. A representative section of tumor is submitted for electron microscopy, cytogenetics, quick-fix, and Tissue Bank. A representative section of normal kidney is submitted for electron microscopy, immunofluorescence, and for Tissue Bank.

Micro A1: tumor to deep margin, 2 frags, [REDACTED]

Micro A2: tumor to kidney capsule, 2 frags, [REDACTED]

Micro A3: tumor to perirenal fat, 2 frags, [REDACTED]

Micro A4: tumor to renal sinus fat and tumor to normal kidney, 2 frags, [REDACTED]

Micro A5: T1 quick-fix, 1 frag, [REDACTED]

Micro A6: T2 quick-fix, 1 frag, [REDACTED]

[page 2 of 6]
[REDACTED]

[REDACTED]

[page 3 of 6]
Date of Birth: [REDACTED]

Pathology Report

Micro A8: normal kidney, 1 frag, RSS.

Part B, labeled "#2 - regional nodes", consists of one fragment of yellow/gray/tan fibroadipose tissue measuring 2.6 x 1.5 x 1.1 cm. Five possible lymph nodes are identified, ranging in size from 0.2-0.6 cm in greatest dimension. The entire specimen is submitted for histologic evaluation.

Micro B1: five possible lymph nodes, 5 frags, [REDACTED]

Micro B2: remaining tissue, multiple frags, [REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

ADDENDUM

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

RIGHT KIDNEY, NEPHRECTOMY:

MINIMAL CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, MOST LIKELY AGE-RELATED (SEE NOTE)

NOTE:

The kidney parenchyma sample examined shows minimal chronic changes, within the expected range for a [REDACTED]. There is minimal focal global glomerulosclerosis (0.8% of glomeruli), minimal tubular atrophy and interstitial fibrosis (less than 2% of the parenchyma), and a mild degree of vascular sclerosis.

The kidney parenchyma has been reviewed by [REDACTED], Renal Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A8) were evaluated using HE, PAS, Jones silver methenamine, and AFOG (trichrome) stains.

The sample consists of cortex and medulla. There are 261 glomeruli present, of which 2 (0.8%) are globally sclerosed. The remaining glomeruli show no significant expansion of the mesangial areas. There are no discernible craters or double contours of the glomerular capillary wall basement membranes. Less than 2% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit a mild to focally moderate degree of sclerosis with isolated evidence of hyaline degeneration.

[Clinical history: obesity, COPD, hypertension, osteoarthritis, serum creatinine 1.0 to 1.2 mg/dL, glucose 97-203 mg/dL]

[page 4 of 6]
10/10/10

[page 5 of 6]
KARYOTYPE: see interpretation

METAPHASES COUNTED: 0 ANALYZED: 0 SCORED: 0 BANDING: GTG

INTERPRETATION:

Attempted cytogenetic analysis was unsuccessful because both samples, T1 and T2, were contaminated upon receipt.

INDICATION FOR TEST:

?

[page 6 of 6]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 4e55b7af-2b57-4a98-984e-ff4ded78432b (TCGA-CZ-5985.AB7974AF-C359-4A8B-8669-84D5D07C3A46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).